CCG case CUPP-B52H — CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8f49465c-7a49-451e-9688-3971dd1a7756

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Finland; Age: 90 years or older (exact value withheld by GDC); Vital status: Dead; Days to death: 3,153 days (8.6 years); Year of death: 2009; Cause of death: Cancer Related.

Diagnoses (3)
1. Squamous cell carcinoma, metastatic, NOS (the primary disease): ICD-O-3 morphology code: 8070/6; ICD-10 code: C80; Tissue or organ of origin: Unknown primary site; Site of resection or biopsy: Head, face or neck, NOS; Classification of tumor: metastasis; Age at diagnosis: 90 years or older (exact value withheld by GDC); Year of diagnosis: 2001; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC clinical T: T0; AJCC clinical N: N2a; AJCC clinical M: M0; AJCC pathologic T: T0; AJCC pathologic N: N2a; AJCC pathologic M: M0; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Head, Face or Neck, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 15; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Partial Response; Timepoint category: Postoperative.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Residual disease: R0; Timepoint category: First Treatment.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS, postoperative.
2. Subsequent primary of the lung (histology not recorded by GDC). Age at diagnosis: 90 years or older (exact value withheld by GDC); Year of diagnosis: 2010; Days to diagnosis: 3,153 days (8.6 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Initial Diagnosis.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Initial Diagnosis.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
3. Subsequent primary of the breast (histology not recorded by GDC). Age at diagnosis: 90 years or older (exact value withheld by GDC); Year of diagnosis: 2010; Days to diagnosis: 3,153 days (8.6 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Initial Diagnosis.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Initial Diagnosis.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.

Follow-up (2 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 70; ECOG performance status: 2.
- Follow-up contact recording only the day: day 3,153.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 63 kg; Height: 165 cm; BMI: 23.1.

Exposures
- Tobacco smoking status: Smoker at Diagnosis; Pack years smoked: 60.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample CUPP-B52H-NT1-A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide CUPP-B52H-NT1-A-1-0-S1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample CUPP-B52H-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide CUPP-B52H-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 45; Percent normal cells: 20; Percent necrosis: 5; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
